Somatic mutation profile of tumor specimen TCGA-76-6283-01A (aliquot TCGA-76-6283-01A-11D-1845-08) from TCGA case TCGA-76-6283, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-76-6283-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 339f6015-d033-43cf-b0b3-780b3161a940.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6283-10A (Blood Derived Normal), aliquot TCGA-76-6283-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0632d63a-1b51-434a-a074-a500e46c1859

The open-access MAF lists 95 somatic variants for this specimen: 74 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 2, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.39_41del p.R15del | In Frame Del (DEL) | VAF 54/68 reads (79%) | catalogued as rs1114167625; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RB1 | c.951_954del p.S318Nfs*13 | Frame Shift Del (DEL) | VAF 42/52 reads (81%) | catalogued as rs1566194323; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 49/57 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.13010C>T p.T4337M | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs527236137, CM065508, COSV100241849; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.746C>A p.S249* (on ENST00000340800 / NM_022977.2; = p.S208* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as COSV100539024, COSV61616017; called by muse, mutect2, varscan2
- ADAMTS12 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.158); catalogued as COSV100711610; called by muse, mutect2, varscan2
- ADGRV1 | c.11060G>A p.R3687H | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs762481926, COSV67979116; called by muse, mutect2, varscan2
- ADGRV1 | c.17063G>A p.R5688Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs374682222; called by muse, mutect2, varscan2
- ADGRV1 | c.17817A>T p.K5939N | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101316437; called by muse, mutect2, varscan2
- AICDA | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); catalogued as rs759799595, COSV57563513; called by muse, mutect2, varscan2
- ALAS1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59627385; called by muse, mutect2, varscan2
- ARHGEF9 | c.1261A>G p.R421G | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99492342; called by muse, mutect2, varscan2
- ATG12 | c.163dup p.I55Nfs*2 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | catalogued as rs1227450075; called by mutect2, varscan2
- ATP8A1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs374228770; called by muse, mutect2, varscan2
- AXDND1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 145/424 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs367975765; called by muse, mutect2, varscan2
- BNIP1 | c.270-1G>A p.X90_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as rs1295470360, COSV99199440; called by muse, mutect2, varscan2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2, varscan2
- CCNF | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs527471283, COSV99564097; called by muse, mutect2, varscan2
- CD163L1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100550613; called by muse, varscan2
- CENPE | c.5014C>T p.Q1672* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99478982; called by muse, mutect2
- CNTNAP4 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV56662156; called by muse, mutect2, varscan2
- COL3A1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.69); catalogued as COSV100483664; called by muse, mutect2, varscan2
- CPT1A | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.192); catalogued as rs745680805, COSV99681564; called by muse, mutect2, varscan2
- CSNK1G3 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100631769; called by muse, mutect2, varscan2
- DCAF12L1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100948371, COSV100948436; called by muse, mutect2
- DGKA | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV59384571; called by muse, mutect2, varscan2
- DPP9 | c.454C>T p.L152F (on ENST00000598800; = p.L181F on NM_139159.5) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99506475; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L4A | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs562929678, COSV54865021, COSV54866254; called by muse, mutect2, varscan2
- FCAMR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs773370049, COSV100249726; called by muse, mutect2, varscan2
- FSCN2 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100585582; called by muse, mutect2, varscan2
- GABRG2 | c.782A>T p.Q261L (on ENST00000361925 / NM_001375343.1; = p.Q221L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV100729832; called by muse, mutect2, varscan2
- GOT2 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99803961; called by muse, mutect2
- INTS10 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762988127, COSV101208738; called by muse, mutect2, varscan2
- IPP | c.1600C>G p.L534V | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV100739701; called by muse, mutect2, varscan2
- KIAA1109 | c.7840C>T p.R2614W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764836068, COSV52694447; called by muse, mutect2, varscan2
- KLHL4 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs754811390, COSV100910131; called by muse, mutect2, varscan2
- KLK9 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV99144085; called by muse, mutect2, varscan2
- LAS1L | c.617T>A p.I206K | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV100408678; called by muse, mutect2, varscan2
- MED12 | c.6014C>A p.T2005N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV100379741; called by muse, mutect2, varscan2
- MLST8 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs975191408, COSV100063979; called by muse, mutect2, varscan2
- NDFIP1 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as COSV99551193; called by muse, mutect2, varscan2
- NUP210L | c.5362G>T p.A1788S | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as rs754089610, COSV99668981; called by muse, mutect2
- OR2T33 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1486760162, COSV58817652; called by muse, mutect2, varscan2
- PCDH11X | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100014782; called by muse, mutect2, varscan2
- PHACTR4 | c.1975C>T p.R659* (on ENST00000373839 / NM_001350159.2; = p.R669* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 10/206 reads (5%) | catalogued as rs1395108790; called by muse, mutect2
- PIBF1 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100411895; called by muse, mutect2
- PITPNM3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.857); catalogued as rs776334168, COSV99339007; called by muse, mutect2, varscan2
- POTEH | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1193900236, COSV100625214; called by muse, mutect2, varscan2
- PYHIN1 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV100932409; called by muse, varscan2
- SERPINI1 | c.893A>C p.E298A | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99855374; called by muse, varscan2
- SIGLEC8 | c.1184C>A p.A395E | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1250187322, COSV100367382; called by muse, mutect2, varscan2
- SLC25A32 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99884659; called by muse, mutect2, varscan2
- SLC28A1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs116070802; called by muse, mutect2, varscan2
- SSH1 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100425821; called by muse, mutect2, varscan2
- STK26 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs981028398, COSV100049255; called by muse, mutect2, varscan2
- SULT2B1 | c.380C>T p.P127L (on ENST00000201586 / NM_177973.2; = p.P112L on NM_004605.2) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571994; called by muse, mutect2, varscan2
- TAF7L | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs149116664, COSV61257000; called by muse, mutect2, varscan2
- TREML2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs756957713, COSV101530188, COSV72439204; called by muse, mutect2, varscan2
- TRPC7 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs758800404, COSV61464424; called by muse, mutect2, varscan2
- TSHZ2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141167641, COSV61586883; called by muse, mutect2, varscan2
- USH2A | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as rs762558966, COSV100241853; called by muse, mutect2, varscan2
- VPS13D | c.9482A>G p.N3161S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99169290; called by muse, mutect2, varscan2
- WDR90 | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 64/173 reads (37%) | catalogued as rs957832548, COSV99554109; called by muse, mutect2, varscan2
- ZC3H18 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); catalogued as COSV56326307; called by muse, mutect2, varscan2
- ZDHHC4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781761812, COSV60105939; called by muse, mutect2, varscan2
- ZNF592 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100246104; called by muse, mutect2, varscan2
- ZSCAN29 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99539401; called by muse, mutect2, varscan2
- MED13 | c.2181+1_2181+5del p.X727_splice | Splice Site (DEL) | VAF 27/30 reads (90%) | called by mutect2, pindel, varscan2
- NKTR | c.1319del p.K440Rfs*26 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- SOWAHC | c.1130del p.K377Rfs*6 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TCF12 | c.1677_1692del p.S559Rfs*3 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- UPF3B | c.762_765del p.D254Efs*8 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel
- ZFR | c.2287_2290del p.S763Nfs*22 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2268C>T p.S756= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100933219; called by muse, mutect2, varscan2
- ABCC10 | c.4401C>T p.R1467= (on ENST00000372530 / NM_001198934.2; = p.R1439= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV99767909; called by muse, mutect2, varscan2
- ANOS1 | c.699C>T p.D233= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs756360027, COSV99391358; called by muse, varscan2
- CRTC3 | c.1623C>T p.C541= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs755359204, COSV99185788; called by muse, mutect2, varscan2
- DNAH1 | c.9381G>A p.S3127= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1432994135, COSV101324961, COSV70227159; called by muse, mutect2, varscan2
- EPHA8 | c.2569C>T p.L857= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99385608; called by muse, mutect2, varscan2
- GADD45A | c.381G>T p.V127= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100921476; called by muse, varscan2
- GPRIN2 | c.234T>G p.S78= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100966467; called by muse, mutect2, varscan2
- HMCN1 | c.15282C>T p.S5094= | Silent (SNP) | VAF 49/85 reads (58%) | catalogued as rs371625429, COSV54897939; called by muse, mutect2, varscan2
- HSPB7 | c.453A>G p.A151= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100318032; called by muse, mutect2, varscan2
- KIAA1109 | c.6954T>C p.A2318= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99174573; called by muse, mutect2, varscan2
- KRTAP26-1 | c.333C>T p.S111= | Silent (SNP) | VAF 98/165 reads (59%) | catalogued as rs1169401340, COSV100860478; called by muse, mutect2, varscan2
- LAMA3 | c.4512G>A p.A1504= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs746501037, COSV100557092; called by muse, mutect2, varscan2
- ONECUT1 | c.219G>A p.R73= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100009413; called by muse, mutect2, varscan2
- SENP1 | c.981G>A p.Q327= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99137154; called by muse, mutect2, varscan2
- SLC10A7 | c.516G>A p.Q172= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53886256; called by muse, mutect2, varscan2
- SYCP2 | c.2208G>A p.S736= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as rs1312608655, COSV62767835; called by muse, mutect2, varscan2
- TAP2 | c.1611T>C p.Y537= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as COSV100886947; called by muse, mutect2, varscan2
- TBX22 | c.667C>A p.R223= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as CD013205, COSV100960640, COSV64784937; called by muse, mutect2
- VAV1 | c.1131C>T p.N377= | Silent (SNP) | VAF 69/218 reads (32%) | catalogued as rs61750002, COSV100409448; called by muse, mutect2, varscan2
- MIA2 | c.1887+45G>T | Intron (SNP) | VAF 34/85 reads (40%) | catalogued as COSV99696917; called by muse, mutect2, varscan2
